Somatic mutation profile of tumor specimen TCGA-D8-A27F-01A (aliquot TCGA-D8-A27F-01A-11D-A16D-09) from TCGA case TCGA-D8-A27F, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 40.3 years (14,731 days).
Specimen TCGA-D8-A27F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a506f316-91aa-4e6c-b8c5-eed8041743d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A27F-10A (Blood Derived Normal), aliquot TCGA-D8-A27F-10A-01D-A16D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/deb41d13-cc6b-4fb5-a74f-b78351e5c602

The open-access MAF lists 65 somatic variants for this specimen: 51 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 13, Frame Shift Del 3, In Frame Del 3, Nonsense Mutation 2, Splice Site 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC5 | c.3301C>T p.R1101W | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.583); catalogued as rs11552530, COSV55597202; called by muse, mutect2, varscan2
- ADPRH | c.140A>T p.D47V | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.033); catalogued as COSV63695995; called by muse, mutect2, varscan2
- AGT | c.740C>A p.A247D | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100794353; called by muse, mutect2
- ANK1 | c.1117A>G p.T373A | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV55897725; called by muse, mutect2, varscan2
- ANKLE1 | c.1910G>T p.R637L (on ENST00000394458; = p.R583L on NM_152363.6) | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101082280, COSV66732028; called by muse, mutect2
- APOBEC2 | c.559G>A p.V187I | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs1349608858, COSV55143768; called by muse, mutect2, varscan2
- APPBP2 | c.1548T>A p.D516E | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV50030288; called by muse, mutect2, varscan2
- BAG6 | c.1595A>G p.Q532R (on ENST00000676571; = p.Q485R on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as COSV52995798; called by muse, mutect2, varscan2
- C6orf89 | c.751C>G p.H251D (on ENST00000373685; = p.H258D on NM_152734.4) | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as COSV62103475; called by muse, mutect2, varscan2
- CARD9 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV53733353, COSV53738425; called by muse, mutect2, varscan2
- CSMD2 | c.10052A>G p.D3351G | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.071); catalogued as COSV53969891; called by muse, mutect2, varscan2
- CSMD3 | c.308T>C p.I103T | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52337320; called by muse, mutect2, varscan2
- ENPP7 | c.136G>C p.D46H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs782250551, COSV60387845, COSV60388054; called by muse, mutect2
- EPB41L5 | c.274G>C p.A92P | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV55358597; called by muse, mutect2, varscan2
- FAM90A1 | c.1232C>G p.A411G | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs1169090772, COSV56715281; called by muse, mutect2
- FLG2 | c.2984G>A p.S995N | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.033); catalogued as rs536296630, COSV66174145; called by muse, mutect2, varscan2
- GDAP1 | c.919A>G p.T307A | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.146); catalogued as rs1356175561, COSV55187523; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HMCN1 | c.2727G>T p.L909F | Missense Mutation (SNP) | VAF 85/162 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs775972475, COSV54946375; called by muse, mutect2, varscan2
- HPS3 | c.2285T>A p.F762Y | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.331); catalogued as COSV56057802; called by muse, mutect2, varscan2
- HSD3B1 | c.156C>A p.N52K | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV52492525; called by muse, mutect2, varscan2
- HUWE1 | c.8342G>A p.G2781E | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.059); catalogued as COSV53366296; called by muse, mutect2, varscan2
- IL11 | c.17G>C p.R6P | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.26); PolyPhen benign (0.155); catalogued as COSV52774104; called by muse, mutect2, varscan2
- IL23A | c.163-1G>T p.X55_splice | Splice Site (SNP) | VAF 3/38 reads (8%) | catalogued as COSV99950669; called by muse, mutect2
- ITSN2 | c.2203G>C p.A735P | Missense Mutation (SNP) | VAF 118/274 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.043); catalogued as COSV61954687; called by muse, mutect2, varscan2
- KCTD18 | c.914C>A p.T305K | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.013); catalogued as COSV104417367, COSV63345237; called by muse, mutect2
- LFNG | c.673G>A p.V225I (on ENST00000222725 / NM_001040167.2; = p.V96I on NM_002304.2) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs76051534; called by muse, mutect2, varscan2
- MYBL1 | c.1204G>T p.E402* | Nonsense Mutation (SNP) | VAF 54/134 reads (40%) | catalogued as COSV72919263; called by muse, mutect2, varscan2
- MYF6 | c.71C>A p.P24Q | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1395774465, COSV57353696, COSV57353820; called by muse, mutect2, varscan2
- NEDD9 | c.1879G>T p.D627Y | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65223608; called by muse, mutect2
- OR4C46 | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.558); catalogued as rs745680497, COSV60221491; called by muse, mutect2
- OR5W2 | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV60618837; called by muse, mutect2, varscan2
- PHOSPHO2 | c.578A>G p.D193G | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55870088; called by muse, mutect2, varscan2
- PIK3CD | c.975C>G p.I325M | Missense Mutation (SNP) | VAF 37/50 reads (74%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); catalogued as COSV63132186; called by muse, mutect2, varscan2
- PKLR | c.1401T>G p.C467W | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); catalogued as COSV61362687; called by muse, mutect2, varscan2
- PLIN4 | c.520C>T p.Q174* (on ENST00000301286; = p.Q189* on NM_001367868.2) | Nonsense Mutation (SNP) | VAF 54/100 reads (54%) | catalogued as rs775560282, COSV56699772; called by muse, mutect2, varscan2
- RAB14 | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.51); catalogued as COSV53054313; called by muse, mutect2, varscan2
- RELN | c.6603C>G p.N2201K | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.373); catalogued as COSV100633616, COSV59037159; called by muse, mutect2, varscan2
- SALL2 | c.43G>C p.D15H | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV58102238, COSV58106188; called by muse, mutect2, varscan2
- SELENOP | c.1036C>G p.R346G | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV62792438, COSV62794425; called by muse, mutect2, varscan2
- SIGLEC5 | c.1644G>C p.K548N | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.755); catalogued as COSV55784580; called by muse, mutect2, varscan2
- SLC9A5 | c.187+1G>T p.X63_splice | Splice Site (SNP) | VAF 10/35 reads (29%) | catalogued as COSV50772100; called by muse, mutect2, varscan2
- TP53 | c.723del p.C242Afs*5 | Frame Shift Del (DEL) | VAF 64/103 reads (62%) | catalogued as COSV53025058, COSV53153033, COSV53211006; called by mutect2, pindel, varscan2
- UBXN2B | c.626G>C p.R209T | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs747002448, COSV68309901; called by muse, mutect2, varscan2
- ZCWPW2 | c.780C>A p.N260K | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as rs778398876, COSV67501622; called by muse, mutect2, varscan2
- ZFHX4 | c.5803G>A p.G1935S | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV51499746; called by muse, mutect2, varscan2
- ZNF80 | c.407G>A p.S136N | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV57360546, COSV57362796; called by muse, mutect2, varscan2
- BAP1 | c.2010_2035del p.Y671Lfs*37 | Frame Shift Del (DEL) | VAF 35/79 reads (44%) | called by mutect2, pindel, varscan2
- CCNL1 | c.712_720del p.V238_F240del | In Frame Del (DEL) | VAF 14/93 reads (15%) | called by mutect2, pindel, varscan2
- COL1A1 | c.3329_3355del p.H1110_G1118del | In Frame Del (DEL) | VAF 11/27 reads (41%) | called by mutect2, pindel, varscan2
- DSP | c.5607_5617del p.Y1871Gfs*5 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | called by mutect2, pindel, varscan2
- SRRM4 | c.1241_1252del p.P414_T417del | In Frame Del (DEL) | VAF 3/26 reads (12%) | called by mutect2, pindel
- CD44 | c.1266G>C p.S422= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV53530305, COSV53531751; called by muse, mutect2, varscan2
- CDKL4 | c.75C>T p.T25= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as rs56089528, COSV66511248; called by muse, mutect2, varscan2
- EGFR | c.2874C>A p.R958= | Silent (SNP) | VAF 46/180 reads (26%) | catalogued as COSV51853702; called by muse, mutect2, varscan2
- IGSF10 | c.4875A>T p.P1625= | Silent (SNP) | VAF 79/217 reads (36%) | catalogued as COSV56792705; called by muse, mutect2, varscan2
- ITGA11 | c.2457A>T p.A819= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV59882535; called by muse, mutect2, varscan2
- KCNG1 | c.339C>T p.N113= | Silent (SNP) | VAF 32/40 reads (80%) | catalogued as rs764980541, COSV65368849; called by muse, mutect2, varscan2
- NFIX | c.903C>G p.S301= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV62179036, COSV62181527; called by muse, mutect2, varscan2
- OR10G2 | c.768C>T p.Y256= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV101606956; called by muse, mutect2, varscan2
- SLC34A1 | c.276C>G p.P92= | Silent (SNP) | VAF 26/42 reads (62%) | catalogued as COSV60998989; called by muse, mutect2, varscan2
- TCTA | c.198G>A p.G66= | Silent (SNP) | VAF 36/58 reads (62%) | catalogued as COSV55534036, COSV55534522; called by muse, mutect2, varscan2
- TSPEAR | c.1059C>G p.V353= | Silent (SNP) | VAF 106/276 reads (38%) | catalogued as COSV59982220; called by muse, mutect2, varscan2
- ZC3H3 | c.2199G>A p.L733= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV52795351; called by muse, mutect2
- ZNF407 | c.5550C>G p.L1850= | Silent (SNP) | VAF 28/34 reads (82%) | catalogued as COSV55272569; called by muse, mutect2, varscan2
- MUC2 | chr11:1099436 G>T | 5'Flank (SNP) | VAF 9/93 reads (10%) | catalogued as rs765317281; called by muse, varscan2
